Surgical pathology report (de-identified scan), TCGA case TCGA-55-8299, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8299-01A (Primary Tumor).

[page 1 of 4]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

- A. - G.) LUNG, RIGHT, UPPER LOBE, PERIBRONCHIAL (N11R), HILAR (N10R X3), LOWER PARATRACHEAL (N4R), SUBCARINAL (N7) LYMPH NODES, LOBECTOMY WITH REGIONAL LYMPH NODE DISSECTION:
- POORLY DIFFERENTIATED ADENOCARCINOMA.
- 2.3 cm in maximum dimension.
- Visceral pleura invasion: NOT IDENTIFIED.
- MARGIN STATUS: NEGATIVE.
- EIGHT LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/8).
- SEE PATHOLOGIC TUMOR STAGING SUMMARY BELOW.

PATHOLOGIC TUMOR STAGING SUMMARY:

Type and grade: Adenocarcinoma, poorly differentiated.

Primary tumor: pT1b.

Regional lymph nodes: pN0 (0/8 lymph nodes).

Distant metastasis: Not applicable.

Pathologic stage: IA.

Lymphovascular invasion: Present.

Margin status: R0.

Lung Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, [REDACTED] and CAP protocol, [REDACTED]

[page 2 of 4]
Procedure:	Lobectomy.
Specimen type:	Lung, upper lobe.
Specimen laterality:	Right.
Specimen integrity:	Intact.
TUMOR FEATURES:	
Tumor site:	Right lung, upper lobe.
Tumor size:	Greatest dimension: 2.3 cm. Additional dimensions: 2.1 x 1.9 cm.
Tumor focality:	Unifocal.
Histologic type:	Adenocarcinoma.
Histologic grade:	Poorly differentiated.
Lymphovascular invasion:	Present.
Perineural invasion:	Not identified.
Visceral pleura invasion:	Not identified.
Tumor extension into extrapulmonary structures:	Absent.
Treatment effect:	Not applicable.
LYMPH NODES:	Eight lymph nodes, negative for metastasis.
MARGIN EVALUATION:	Negative (R0).
Distance to closest margin:	3.7 cm from bronchial margin.
Bronchial margin:	Uninvolved by invasive carcinoma.
Vascular margin:	Uninvolved by invasive carcinoma.
Parenchymal margin:	Uninvolved by invasive carcinoma.
Parietal pleural margin:	Not applicable.
Chest wall margin:	Not applicable.
Other margins:	Not applicable.
PATHOLOGIC TUMOR STAGING SUMMARY:	
Primary tumor:	pT1b (2.3 cm in greatest dimension).
Regional lymph nodes:	pN0 (0/8 lymph nodes).
Distant metastasis:	Not applicable.
Margin status:	R0.
Pathologic stage:	IA.
Additional pathologic findings:	Emphysematous changes.
Comment:	Not applicable.

[page 3 of 4]
FINAL SURGICAL PATHOLOGY REPORT

A. Lung;RUL
B. N10R
C. N10R#2
D. N10R#3
E. N11R
F. N4R
G. N7

Clinical History/Operative Dx:

Right lung carcinoma

Intraoperative Diagnosis:

A. Lung, right upper lobe, lobectomy: Bronchial margins negative [REDACTED] The intraoperative interpretation(s) was/were performed and rendered at [REDACTED]
[REDACTED]

Gross Description:

A. Part A lung, right upper lobe. Initially received in a fresh state for frozen section analysis is a 155 gram lobe of lung, 17.0 x 11.7 x 3.2 cm. The pleura is glistening light tan to deep purple-red with moderate anthracotic pigmentation. The bronchial margin extends up to 0.6 cm, and 2.3 cm in diameter, closed by numerous surgical staples which is now removed to demonstrate bronchial pathways grossly free of tumor involvement. Anteriorly the pleura demonstrates a dimpled appearance and upon sectioning reveals a well circumscribed, irregular dense light gray tumor mass, 2.3 x 2.1 x 1.9 cm, grossly approaching within 3.7 cm of the bronchial margin. The bronchial margin is trimmed and submitted for frozen section analysis, with residual frozen tissue submitted in A1 for permanent sections. Examination of the adjacent lobar tracts do not demonstrate gross tumor involvement. Sectioning through the remainder of the lobe demonstrates consolidated, "wet" pink and gray-red lung parenchyma, without additional discrete nodularity. No grossly distinct lymph node tissue appreciated. Representative sections are submitted for microscopic evaluation.

Cassette summary: A1) bronchial margin, frozen section, A2-A4) tumor mass anterior pleura represented, five pieces, A5) pulmonary vascular margins trimmed and submitted, A6) representation of grossly uninvolved lung. [REDACTED]

B. Part B designated N10R. Received in formalin is light pink to speckled gray anthracotic lymph node candidate, 0.8 x 0.6 x 0.3 cm. The specimen is submitted intact in B1. [REDACTED]

C. Part C designated N10R #2. Received in formalin is a light pink to speckled gray anthracotic lymph node candidate fragment, 0.7 x 0.5 x 0.4 cm. The fragment is submitted in its entirety, intact in C1. [REDACTED]

D. Part D designated N10R #3. Received in formalin is a light pink to speckled gray anthracotic lymph node candidate, 0.7 x 0.3 x 0.3 cm. The lymph node is submitted intact in D1. [REDACTED]

E. Part E designated N11R. Received in formalin is a light pink to speckled gray anthracotic lymph node candidate, 1.3 x 0.8 x 0.5 cm. The specimen is bisected and submitted in E1. [REDACTED]
[REDACTED]

[page 4 of 4]
FINAL SURGICAL PATHOLOGY REPORT

F. Part F designated N4R. Received in formalin are multiple lobular and tattered fragments of light pink to speckled gray anthracotic lymph node tissue, measuring in aggregate of 2.3 x 2.0 x 0.4 cm. Examination reveals up to five lymph node candidates ranging from 0.3 - 0.6 cm. Entirely submitted for microscopic evaluation.

Cassette summary: F1) three tattered lymph node candidates/fragments, F2) two lymph node candidates/fragments. [REDACTED]

G. Part G designated N7. Received in formalin are two light pink to speckled gray anthracotic lymph node candidates/fragments, 0.5 and 1.1 cm each. Tissue is entirely submitted for microscopic evaluation in G1 and G2, one bisected node each. [REDACTED]

Microscopic Description:

A. Sections demonstrate lung tissue, containing an infiltrating neoplasm, composed of large polygonal cells with clear, amphophilic, to eosinophilic cytoplasm, large vesicular nuclei, with prominent nucleoli. Individual cell necrosis is present. Rare atypical mitoses are seen. Neutrophils are present in intimate association with tumor cells in some areas. Immunohistochemical studies are performed on the tumor. The neoplastic cells show strong and diffuse positivity for CK7, and MOC-31. ER shows focal weak nuclear staining. Rare cells show positive staining for mammoglobin and Napsin-A. Rare tumor cells are positive for TTF-1. CK20, CK5/6, p63, S100, Melan-A, GCDFP-15, and villin immunostains are negative. D2-40 and CD31 confirm the presence of extensive lymphovascular invasion. All staining controls are appropriately reactive. The pattern of immunoreactivity is most compatible with adenocarcinoma. Focal TTF-1 staining suggests primary lung origin.

B. Sections demonstrate one benign lymph node with anthracotic pigment laden macrophages, negative for metastasis.

C. Sections demonstrate one benign lymph node with anthracotic pigment laden macrophages, negative for metastasis.

D. Sections demonstrate one benign lymph node with anthracotic pigment laden macrophages, negative for metastasis.

E. Sections demonstrate one benign lymph node with anthracotic pigment laden macrophages, negative for metastasis.

F. Sections demonstrate lymphoid tissue, with anthracotic pigment laden macrophages, negative for metastatic carcinoma.

G. Sections demonstrate lymphoid tissue, with anthracotic pigment laden macrophages, negative for metastatic carcinoma.

Source: NCI Genomic Data Commons file a2fb3151-049c-4ae0-97d0-8127f5cb8812 (TCGA-55-8299.A63E89AA-463D-4A53-9176-B4FD917E6416.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).